Somatic mutation profile of tumor specimen TCGA-BC-A112-01A (aliquot TCGA-BC-A112-01A-11D-A12Z-10) from TCGA case TCGA-BC-A112, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 80.8 years (29,511 days).
Specimen TCGA-BC-A112-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 282b4fd3-e0b8-4f6f-b7d6-f78bac7e7255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A112-11A (Solid Tissue Normal), aliquot TCGA-BC-A112-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b79e7ab5-dcc8-4f9a-902a-2e2027e51ea9

The open-access MAF lists 991 somatic variants for this specimen: 931 protein-altering or splice-affecting, 36 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 822, Missense Mutation 76, Silent 36, Splice Site 13, Intron 9, RNA 7, Splice Region 5, Frame Shift Del 5, Nonsense Mutation 5, 5'UTR 4, In Frame Del 3, 3'UTR 2.

Variants (750 of 991; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.577dup p.L193Pfs*32 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | catalogued as rs180177241; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- CFTR | c.2089dup p.R697Kfs*33 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | catalogued as rs397508341; ClinVar: pathogenic; called by pindel, varscan2
- EXT1 | c.579dup p.N194* | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs1554601519; ClinVar: likely pathogenic; called by pindel, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 78/397 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- POR | c.1329dup p.I444Hfs*6 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs786205875; ClinVar: pathogenic; called by pindel, varscan2
- REEP1 | c.512dup p.P172Tfs*15 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | catalogued as rs387906263; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- AEBP1 | c.1161dup p.I388Hfs*9 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | catalogued as rs780326187; called by mutect2, pindel
- AK5 | c.611A>G p.Q204R (on ENST00000354567 / NM_174858.3; = p.Q178R on NM_012093.4) | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV58357044; called by mutect2, varscan2
- AMOTL2 | c.584dup p.L196Tfs*7 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | catalogued as rs778020599; called by pindel, varscan2
- AP1B1 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58023405; called by mutect2, varscan2
- ARHGEF28 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55269916; called by mutect2, varscan2
- ARMC9 | c.1160T>G p.V387G | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63023652; called by mutect2, varscan2
- ATP8A2 | c.3428dup p.T1144Dfs*27 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | catalogued as rs1270222033; called by pindel, varscan2
- BICD1 | c.2528A>T p.Q843L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.225); catalogued as COSV55688063, COSV99862076; called by mutect2, varscan2
- BRCA1 | c.4822G>A p.A1608T | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1567775064, COSV58795003; ClinVar: uncertain significance; called by mutect2, varscan2
- CAND2 | c.940T>G p.Y314D (on ENST00000456430 / NM_001162499.2; = p.Y221D on NM_012298.3) | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV55994421; called by mutect2, varscan2
- CAPN3 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as CD951643, COSV55521974; called by mutect2, varscan2
- CCDC141 | c.3674C>T p.S1225F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs773697882, COSV55382199, COSV99837534; called by mutect2, varscan2
- CCR2 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV52750032; called by mutect2, varscan2
- CDC37L1 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1316966505, COSV67866412; called by mutect2, varscan2
- CDC42BPB | c.4842dup p.S1615Lfs*36 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | catalogued as rs781316314; called by mutect2, pindel, varscan2
- CDK12 | c.4210C>T p.R1404C (on ENST00000447079 / NM_016507.4; = p.R1395C on NM_015083.3) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1172789499, COSV71001611; called by mutect2, varscan2
- CHRNA10 | c.1136dup p.A380Sfs*38 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs748764774; called by pindel, varscan2
- CLTCL1 | c.3888dup p.E1297* | Frame Shift Ins (INS) | VAF 4/50 reads (8%) | catalogued as rs1569157585; called by mutect2, pindel
- COL14A1 | c.4520G>A p.G1507E | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52868075; called by mutect2, varscan2
- CUBN | c.253-1G>C p.X85_splice | Splice Site (SNP) | VAF 20/92 reads (22%) | catalogued as COSV64701966; called by mutect2, varscan2
- CYFIP2 | c.145A>G p.R49G | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV59050433; called by mutect2, varscan2
- DCAF5 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as rs1011482149, COSV58463074; called by mutect2, varscan2
- DDN | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.04); catalogued as COSV60294767; called by muse, varscan2
- DENND11 | c.1188A>C p.Q396H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV72097818; called by mutect2, varscan2
- DGKG | c.1649G>A p.S550N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53972551; called by mutect2, varscan2
- DRD5 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58577915, COSV58578452; called by mutect2, varscan2
- ELN | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52715443; called by muse, mutect2, varscan2
- FADS6 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.563); catalogued as COSV59603818; called by muse, mutect2
- FAM107B | c.388G>T p.E130* (on ENST00000378458 / NM_001320737.1; = p.E305* on NM_031453.3) | Nonsense Mutation (SNP) | VAF 26/125 reads (21%) | catalogued as COSV51692836; called by mutect2, varscan2
- FAM163B | c.410dup p.F138Lfs*88 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | catalogued as rs781724280; called by pindel, varscan2
- FER1L5 | c.4490dup p.L1498Afs*38 (on ENST00000623019; = p.L1471Afs*38 on NM_001293083.2) | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | catalogued as rs1166849888; called by pindel, varscan2
- FKBP10 | c.1034dup p.H346Afs*27 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | catalogued as rs1555616685; called by pindel, varscan2
- GALNTL6 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV72489481; called by mutect2, varscan2
- GUCY1A2 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.497); catalogued as COSV56501651; called by mutect2, varscan2
- GUF1 | c.1336-2A>T p.X446_splice | Splice Site (SNP) | VAF 100/214 reads (47%) | catalogued as COSV55783711; called by mutect2, varscan2
- H2BC14 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV60798774; called by mutect2, varscan2
- H3C11 | c.124dup p.Y42Lfs*39 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs1365353389; called by mutect2, pindel
- HOXC8 | c.527G>C p.R176P | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50002811; called by mutect2, varscan2
- HSPB2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.645); catalogued as rs1462346191, COSV57052542; called by mutect2, varscan2
- IL11 | c.492dup p.S165Lfs*22 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | catalogued as rs1238352663; called by pindel, varscan2
- ITGAV | c.2737G>T p.V913F | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.163); catalogued as COSV53718804; called by mutect2, varscan2
- JAG2 | c.3319C>T p.R1107C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413207667, COSV59308391; called by muse, mutect2, varscan2
- KBTBD13 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1193653136, COSV71351745; called by muse, mutect2, varscan2
- KCNT1 | c.1025dup p.N343Qfs*134 (on ENST00000488444; = p.N362Qfs*134 on NM_020822.3) | Frame Shift Ins (INS) | VAF 7/83 reads (8%) | catalogued as rs778930811; called by mutect2, pindel
- KLHL10 | c.1702A>C p.S568R | Missense Mutation (SNP) | VAF 177/346 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs988225810, COSV53174997; called by mutect2, varscan2
- KLK9 | c.93dup p.N32Qfs*24 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as rs1218682589; called by pindel, varscan2
- KNTC1 | c.5676T>G p.C1892W | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61084068; called by mutect2, varscan2
- LARP7 | c.834A>T p.K278N | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60520388, COSV60522264; called by mutect2, varscan2
- LRP11 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV53333833, COSV53335415; called by mutect2, varscan2
- MLEC | c.741dup p.Q248Tfs*4 | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | catalogued as rs1380388035; called by pindel, varscan2
- MRPL57 | c.251dup p.H85Afs*2 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | catalogued as rs756515265; called by mutect2, pindel
- MTOR | c.1410T>C p.H470= | Splice Region (SNP) | VAF 18/33 reads (55%) | catalogued as COSV63878078; called by muse, mutect2, varscan2
- NCOA1 | c.4326A>T p.*1442Yext*9 | Nonstop Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV56052832; called by mutect2, varscan2
- NLRP2 | c.2900C>G p.P967R | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV54760210; called by mutect2, varscan2
- NRN1L | c.319dup p.R107Pfs*4 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | catalogued as rs759602582; called by pindel, varscan2
- OLFML2B | c.1833dup p.W612Lfs*28 | Frame Shift Ins (INS) | VAF 9/84 reads (11%) | catalogued as rs1343579976; called by mutect2, varscan2
- OR10A2 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56298756; called by mutect2, varscan2
- OR2B11 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.084); catalogued as COSV59511446; called by mutect2, varscan2
- OR51E1 | c.466dup p.A156Gfs*38 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | catalogued as rs1564877761; called by mutect2, pindel
- ORC1 | c.752C>A p.T251N | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV65365172; called by mutect2, varscan2
- P2RX2 | c.306dup p.E103Rfs*169 (on ENST00000343948 / NM_170683.4; = p.R80Pfs*120 on NM_012226.5) | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs1397352517; called by pindel, varscan2
- PANK4 | c.311G>C p.C104S | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV65867466, COSV65867999; called by mutect2, varscan2
- PCNX2 | c.5062G>A p.A1688T | Missense Mutation (SNP) | VAF 73/303 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50889019; called by mutect2, varscan2
- PDE11A | c.2754dup p.S919Lfs*30 | Frame Shift Ins (INS) | VAF 11/216 reads (5%) | catalogued as COSV53709180; called by mutect2, pindel*
- PLD4 | c.310dup p.Q104Pfs*43 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs1353695687; called by pindel, varscan2
- PLEKHA4 | c.194A>G p.D65G | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV54366134; called by muse, mutect2, varscan2
- POGZ | c.260T>G p.V87G | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as COSV55041992; called by mutect2, varscan2
- PRPF40A | c.1483T>A p.S495T | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as COSV62960602; called by mutect2, varscan2
- PRSS55 | c.756dup p.P253Afs*10 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | catalogued as rs751829343; called by mutect2, pindel
- PTK6 | c.914C>A p.S305* | Nonsense Mutation (SNP) | VAF 30/180 reads (17%) | catalogued as COSV53918154; called by mutect2, varscan2
- PTK6 | c.190dup p.H64Pfs*113 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | catalogued as COSV99420987; called by mutect2, pindel
- PTPN21 | c.2782C>T p.Q928* | Nonsense Mutation (SNP) | VAF 46/246 reads (19%) | catalogued as COSV100161325, COSV60852021; called by mutect2, varscan2
- PXDN | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53245992; called by muse, mutect2, varscan2
- R3HDM1 | c.1847G>C p.G616A | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV51532631; called by mutect2, varscan2
- RAD52 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.201); catalogued as COSV57274449; called by mutect2, varscan2
- RANBP9 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV50585846; called by mutect2, varscan2
- RBM15 | c.448dup p.E150Gfs*33 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | catalogued as rs1557890664; called by mutect2, pindel
- RBM15 | c.2319dup p.T774Dfs*36 | Frame Shift Ins (INS) | VAF 7/75 reads (9%) | catalogued as COSV100873442; called by mutect2, pindel
- REM2 | c.216dup p.Y73Lfs*13 | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | catalogued as rs767618692; called by mutect2, pindel
- RGS7 | c.907T>G p.S303A | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV58560389; called by mutect2, varscan2
- RIMS3 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1466678409, COSV65505417; called by mutect2, varscan2
- RNF123 | c.1989dup p.P664Afs*55 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | catalogued as rs35072697; called by mutect2, pindel, varscan2
- RNF166 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as COSV57190103; called by mutect2, varscan2
- RNF26 | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV60991491; called by muse, varscan2
- RPL14 | c.494dup p.I166Dfs*6 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | catalogued as rs1243470255; called by pindel, varscan2
- RTTN | c.3258G>T p.R1086S | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV99732340; called by mutect2, varscan2
- SCIN | c.1149G>T p.Q383H (on ENST00000297029 / NM_001112706.3; = p.Q136H on NM_033128.3) | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51698489, COSV99764939; called by mutect2, varscan2
- SENP6 | c.1751C>G p.P584R | Missense Mutation (SNP) | VAF 131/434 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs1386220260, COSV100519352, COSV59191267, COSV59194578; called by mutect2, varscan2
- SFSWAP | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as COSV55525755; called by mutect2, varscan2
- SGSM2 | c.2936G>A p.R979H (on ENST00000426855 / NM_001098509.2; = p.R1024H on NM_014853.3) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs1267086557, COSV51514052; called by muse, varscan2
- SH3BP4 | c.1208dup p.N403Kfs*2 | Frame Shift Ins (INS) | VAF 7/66 reads (11%) | catalogued as rs766163019; called by pindel, varscan2
- SHOX2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.972); catalogued as COSV55838794; called by muse, varscan2
- SLC35B2 | c.314dup p.M106Dfs*42 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs1219556479; called by pindel, varscan2
- SMARCA4 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.935); catalogued as rs1236388987, COSV60808900; ClinVar: uncertain significance; called by mutect2, varscan2
- SRL | c.1064A>T p.K355M | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as rs1351765820, COSV68424551; called by mutect2, varscan2
- ST8SIA6 | c.691A>T p.N231Y | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66471705; called by mutect2, varscan2
- SWAP70 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as rs753123282, COSV59666890; called by mutect2, varscan2
- SYNE4 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV53325810; called by mutect2, varscan2
- TAGLN3 | c.141dup p.G48Rfs*21 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs762583525; called by mutect2, pindel
- TBC1D10B | c.1879dup p.E627Gfs*73 | Frame Shift Ins (INS) | VAF 6/61 reads (10%) | catalogued as rs771710139; called by mutect2, pindel, varscan2
- TBXT | c.338dup p.K114Qfs*52 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs757779131; called by pindel, varscan2
- TCIRG1 | c.1077dup p.T360Hfs*130 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs1158449736; called by pindel, varscan2
- TMED9 | c.142_144del p.K48del | In Frame Del (DEL) | VAF 39/219 reads (18%) | catalogued as rs1561809116; called by pindel, varscan2
- TNFAIP3 | c.2217dup p.N740Qfs*12 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | catalogued as COSV52800605; called by mutect2, pindel
- TP53BP2 | c.275dup p.G93Wfs*25 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | catalogued as rs1206100374; called by mutect2, pindel
- TSEN54 | c.869dup p.A291Sfs*3 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs1386935097; called by mutect2, pindel
- TTC1 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV51466811; called by mutect2, varscan2
- UMODL1 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV61161494; called by muse, varscan2
- USP31 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV54857076; called by mutect2, varscan2
- WDHD1 | c.2519dup p.L841Afs*22 | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | catalogued as rs1566713826; called by mutect2, pindel
- WDR44 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 89/120 reads (74%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as COSV54168864; called by mutect2, varscan2
- XPO4 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV55013211; called by mutect2, varscan2
- ZC3H7B | c.1592dup p.V532Cfs*2 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs1309914071; called by pindel, varscan2
- ZNF20 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as COSV62000569; called by mutect2, varscan2
- ZNF521 | c.3287G>A p.C1096Y | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64126583, COSV64131822; called by mutect2, varscan2
- ZNF683 | c.68dup p.S24Lfs*14 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | catalogued as rs1208227319; called by mutect2, pindel
- ABCA2 | c.5861dup p.L1955Pfs*54 (on ENST00000614293; = p.L1925Pfs*54 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- ABCA2 | c.2692dup p.L898Pfs*3 (on ENST00000614293; = p.L868Pfs*3 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- ABCA7 | c.2194dup p.Q732Pfs*32 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ABCC6 | c.3307-2dup p.X1103_splice | Splice Site (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- ABI3 | c.346dup p.Q116Pfs*172 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, pindel
- ABL1 | c.2562dup p.S855Qfs*29 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- ABR | c.233dup p.L79Tfs*30 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- ACP2 | c.963dup p.N322Efs*13 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- ACSM4 | c.425dup p.M142Ifs*28 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel, varscan2
- ACTL7B | c.222dup p.I75Hfs*27 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel
- ACTL9 | c.317dup p.E107Rfs*149 | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS13 | c.4024dup p.L1342Pfs*46 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, varscan2
- ADAMTS15 | c.2317dup p.R773Pfs*107 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by pindel, varscan2
- ADAMTS17 | c.998dup p.P334Afs*20 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel
- ADAMTSL3 | c.1967dup p.C656Wfs*27 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ADAMTSL3 | c.2387dup p.L796Ffs*6 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, pindel
- ADAMTSL5 | c.575dup p.V193Rfs*7 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- ADCY5 | c.3061dup p.Q1021Pfs*40 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- ADCY7 | c.3210dup p.T1071Hfs*28 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- ADCY9 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by mutect2, varscan2
- ADGRA3 | c.3081dup p.S1028* | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- ADGRA3 | c.2734dup p.A912Gfs*36 | Frame Shift Ins (INS) | VAF 7/63 reads (11%) | called by mutect2, pindel
- ADRB1 | c.285dup p.F96Lfs*213 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- ADRB1 | c.632dup p.N211Kfs*98 | Frame Shift Ins (INS) | VAF 3/20 reads (15%) | called by mutect2, pindel
- AFAP1 | c.2001+1dup p.X667_splice | Splice Site (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- AFDN | c.4332dup p.R1445Afs*136 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel, varscan2
- AFF1 | c.1696dup p.S566Kfs*103 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel
- AGAP4 | c.1150A>T p.S384C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- AGRN | c.4105+1dup | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel
- AHCY | c.46dup p.A16Gfs*11 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- AHDC1 | c.2363dup p.R789Pfs*60 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- AHDC1 | c.909dup p.A304Cfs*2 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- AHNAK2 | c.117dup p.T40Dfs*2 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- AKAP17A | c.1146dup p.A383Sfs*170 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- AKNA | c.3276dup p.D1093Rfs*19 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- AKNA | c.1696dup p.L566Pfs*16 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- AL358113.1 | c.3919dup p.Y1307Lfs*17 | Frame Shift Ins (INS) | VAF 5/51 reads (10%) | called by mutect2, pindel
- ALDH1B1 | c.343dup p.D115Gfs*27 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ALDH4A1 | c.155dup p.A53Gfs*19 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- ALOXE3 | c.1223dup p.H408Qfs*113 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- ALPK3 | c.4489dup p.E1497Gfs*4 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | called by pindel, varscan2
- AMER3 | c.1396dup p.A466Gfs*12 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- AMER3 | c.2522dup p.L842Pfs*17 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel, varscan2
- ANGPTL7 | c.4dup p.L2Pfs*30 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- ANK1 | c.4615dup p.Q1539Pfs*5 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- ANKLE1 | c.1177dup p.D393Gfs*2 (on ENST00000394458; = p.D339Gfs*2 on NM_152363.6) | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- ANKS6 | c.1087dup p.A363Gfs*11 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- ANTXR1 | c.1607dup p.P537Tfs*46 | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | called by pindel, varscan2
- AP2S1 | c.371dup p.E125Rfs*95 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- AP3D1 | c.2001+1dup p.X667_splice | Splice Site (INS) | VAF 3/17 reads (18%) | called by mutect2, pindel
- APCDD1 | c.377dup p.K127Qfs*62 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel
- APOL3 | c.670dup p.V224Gfs*28 (on ENST00000349314 / NM_145640.2; = p.V153Gfs*28 on NM_014349.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel
- AQP7 | c.799dup p.L267Pfs*28 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ARHGAP31 | c.1304dup p.R436Pfs*4 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by pindel, varscan2
- ARHGEF1 | c.1728dup p.Q577Afs*32 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ARHGEF15 | c.272dup p.D92Rfs*10 | Frame Shift Ins (INS) | VAF 9/77 reads (12%) | called by mutect2, pindel
- ARHGEF18 | c.2886dup p.T963Hfs*77 (on ENST00000359920 / NM_001130955.2; = p.T859Hfs*77 on NM_015318.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- ARHGEF40 | c.492dup p.C165Lfs*16 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- ARHGEF40 | c.3232dup p.E1078Gfs*15 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- ARID4A | c.2990dup p.V998Cfs*5 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel
- ARSH | c.316dup p.R106Pfs*22 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- ARVCF | c.782dup p.L261Ffs*4 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- ASB10 | c.181dup p.A61Gfs*24 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel*
- ASCL3 | c.143dup p.Y49Lfs*3 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- ASIC4 | c.349dup p.L117Pfs*45 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- ASPHD1 | c.541dup p.V181Gfs*145 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- ASPHD2 | c.130dup p.D44Gfs*69 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- ASPRV1 | c.841dup p.E281Gfs*7 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ATG101 | c.248dup p.K84Qfs*63 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- ATG2A | c.5671dup p.R1891Pfs*65 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- ATP8B2 | c.1726dup p.R576Pfs*21 (on ENST00000672630; = p.R543Pfs*21 on NM_001367934.1 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ATP9B | c.2829dup p.T944Hfs*95 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- AUTS2 | c.3425del p.E1142Gfs*76 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by pindel, varscan2
- B4GALNT3 | c.201dup p.L68Sfs*29 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- BAG3 | c.1254dup p.H419Tfs*25 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- BAG6 | c.1212dup p.S405Lfs*15 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel, varscan2
- BAG6 | c.572dup p.Q192Afs*28 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- BAK1 | c.421dup p.H141Pfs*164 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- BAX | c.474+6dup | Splice Region (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- BCAN | c.2661dup p.G888Rfs*122 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- BDKRB2 | c.1125dup p.V376Rfs*29 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by mutect2, pindel
- BICRA | c.3770dup p.S1258Ffs*238 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- BPIFB4 | c.1156dup p.E386Gfs*29 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- BRS3 | c.1173dup p.V392Cfs*47 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- BSG | c.152dup p.P52Afs*8 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- BTBD6 | c.1035dup p.Y346Lfs*39 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- BTN3A1 | c.720dup p.F241Lfs*90 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- C12orf40 | c.1071dup p.S358* | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | called by mutect2, pindel
- C15orf39 | c.1533dup p.Y512Lfs*3 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- C16orf91 | c.244dup p.L82Pfs*36 | Frame Shift Ins (INS) | VAF 7/78 reads (9%) | called by mutect2, pindel
- C1orf115 | c.225dup p.E76Rfs*97 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | called by pindel, varscan2
- C1orf127 | c.1917dup p.H640Afs*47 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- C21orf58 | c.494dup p.S166Kfs*74 | Frame Shift Ins (INS) | VAF 4/53 reads (8%) | called by mutect2, pindel
- C2orf42 | c.1700dup p.L568Sfs*32 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- C7orf50 | c.118dup p.A40Gfs*93 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- C9orf131 | c.1265dup p.N422Kfs*6 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by pindel, varscan2
- CABP2 | c.93dup p.S32Qfs*50 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- CACNA1A | c.3008dup p.E1004Rfs*67 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | called by pindel, varscan2
- CACNA1F | c.5315dup p.L1772Ffs*44 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CACNA1F | c.4715dup p.P1573Tfs*40 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- CACNA1H | c.6755dup p.Q2253Pfs*7 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel
- CAMTA2 | c.1354dup p.E452Gfs*46 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- CARMIL3 | c.2554dup p.S852Ffs*38 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- CASZ1 | c.2547dup p.V850Rfs*43 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- CATSPERG | c.1780dup p.M594Nfs*29 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- CBARP | c.902dup p.S302Ifs*61 (on ENST00000382477; = p.S282Ifs*61 on NM_152769.3) | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by pindel, varscan2
- CBFA2T2 | c.1694dup p.S566Lfs*48 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- CBY2 | c.623dup p.R209Pfs*207 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel, varscan2
- CCDC115 | c.113dup p.W39Lfs*71 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | called by mutect2, pindel
- CCDC63 | c.1481dup p.E495Rfs*13 | Frame Shift Ins (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- CCDC88C | c.5649dup p.R1884Efs*92 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- CD40 | c.682dup p.H228Pfs*79 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | called by pindel, varscan2
- CD93 | c.1675dup p.Q559Pfs*19 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- CDC42BPA | c.4496dup p.N1499Kfs*9 (on ENST00000334218 / NM_001366019.2; = p.N1486Kfs*9 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 7/79 reads (9%) | called by mutect2, pindel
- CDC42EP1 | c.923dup p.P309Sfs*71 | Frame Shift Ins (INS) | VAF 7/71 reads (10%) | called by mutect2, pindel
- CDCP1 | c.681dup p.E228* | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by pindel, varscan2
- CDH1 | c.382dup p.H128Pfs*40 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- CDHR5 | c.1436dup p.E480* (on ENST00000358353 / NM_001171968.2; = p.E486* on NM_021924.5) | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel
- CDK16 | c.1113dup p.H372Tfs*12 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- CDK4 | c.79dup p.H27Pfs*30 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- CDK9 | c.161dup p.N54Kfs*30 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- CELSR2 | c.8641dup p.R2881Pfs*29 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- CEP126 | c.124dup p.Y42Lfs*32 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- CEP68 | c.1349dup p.E451Rfs*19 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- CFAP157 | c.468dup p.Q157Afs*22 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- CHD9 | c.4275dup p.W1426Mfs*3 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- CHRD | c.2387dup p.T797Yfs*14 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel
- CHRM3 | c.1047dup p.A350Rfs*44 | Frame Shift Ins (INS) | VAF 6/70 reads (9%) | called by mutect2, pindel
- CHRNA2 | c.1126dup p.R376Pfs*77 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel
- CHTF18 | c.2599dup p.Q867Pfs*30 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- CLDN14 | c.311dup p.C104Wfs*56 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- CLDN4 | c.271dup p.A91Gfs*21 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- CLEC10A | c.854dup p.H286Pfs*8 (on ENST00000254868 / NM_182906.4; = p.H262Pfs*8 on NM_006344.4) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- CLIP2 | c.1555dup p.I519Nfs*48 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- CLMN | c.614dup p.V206Rfs*24 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- CNR2 | c.505dup p.L169Pfs*13 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- CNTNAP2 | c.3343dup p.V1115Gfs*50 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- COL16A1 | c.2283+1dup p.X761_splice | Splice Site (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- COL18A1 | c.4199dup p.P1402Sfs*100 (on ENST00000359759 / NM_130444.3; = p.P1167Sfs*100 on NM_030582.4) | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- COL27A1 | c.4979dup p.E1661Rfs*4 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- COL4A1 | c.2337dup p.I780Dfs*4 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- COL5A1 | c.935dup p.T313Dfs*10 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- COL6A3 | c.1859dup p.L620Ffs*13 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, pindel, varscan2
- COL6A6 | c.1076dup p.V360Cfs*25 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- COL7A1 | c.6500dup p.L2169Sfs*121 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- COL7A1 | c.5661dup p.P1888Afs*27 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- COL9A3 | c.245dup p.V84Cfs*84 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel
- COMT | c.137dup p.H47Pfs*7 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- COPB1 | c.107dup p.S37Vfs*4 | Frame Shift Ins (INS) | VAF 7/76 reads (9%) | called by mutect2, pindel
- CPA5 | c.1137dup p.I380Dfs*8 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | called by mutect2, varscan2
- CPED1 | c.1049dup p.T351Dfs*4 | Frame Shift Ins (INS) | VAF 6/72 reads (8%) | called by mutect2, pindel
- CPNE5 | c.1703del p.P568Hfs*92 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- CPNE6 | c.1464dup p.R490Afs*36 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- CRACD | c.828dup p.Q277Afs*33 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- CRACR2B | c.698dup p.A234Rfs*118 (on ENST00000525077 / NM_001286606.2; = p.A234Rfs*56 on NM_173584.4) | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- CRB2 | c.2247dup p.R750Efs*37 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- CREBBP | c.5810dup p.P1938Afs*28 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- CRYBA4 | c.237dup p.W80Lfs*22 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- CSAD | c.67dup p.A23Gfs*9 (on ENST00000444623 / NM_001244705.2; = p.A50Gfs*9 on NM_015989.5) | Frame Shift Ins (INS) | VAF 6/72 reads (8%) | called by mutect2, pindel
- CSTF2T | c.165dup p.P56Tfs*17 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, pindel
- CTTN | c.1625dup p.A543Sfs*81 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- CUX2 | c.1398dup p.S467Qfs*5 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by pindel, varscan2
- CYP1A1 | c.327dup p.Y110Lfs*8 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- CYP26C1 | c.1430dup p.R478Afs*115 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- CYP8B1 | c.708dup p.H237Sfs*82 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- DAG1 | c.749dup p.V251Gfs*23 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by pindel, varscan2
- DCHS1 | c.17dup p.I7Hfs*46 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- DDN | c.1371dup p.T458Hfs*44 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- DDR1 | c.1558dup p.Y520Lfs*32 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- DDX51 | c.1224dup p.Q409Afs*31 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- DECR2 | c.691dup p.V231Gfs*61 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel
- DEFA6 | c.178dup p.S60Kfs*3 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- DENND1A | c.2283dup p.T762Hfs*2 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- DENND2D | c.544dup p.A182Gfs*34 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- DENND4C | c.4218dup p.K1407Qfs*18 (on ENST00000434457 / NM_001330640.2; = p.K1358Qfs*18 on NM_017925.7) | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- DGCR8 | c.2266dup p.S756Ffs*11 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- DGKG | c.2151dup p.Q718Afs*44 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- DGLUCY | c.1674dup p.T559Dfs*9 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- DICER1 | c.1711dup p.S571Kfs*3 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | called by mutect2, pindel
- DLG4 | c.1474dup p.R492Pfs*4 (on ENST00000399506 / NM_001321075.3; = p.R535Pfs*4 on NM_001365.4) | Frame Shift Ins (INS) | VAF 3/18 reads (17%) | called by mutect2, pindel
- DLGAP1 | c.204dup p.T69Hfs*103 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- DNAH10 | c.7542dup p.V2515Cfs*3 (on ENST00000409039; = p.V2454Cfs*3 on NM_207437.3) | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | called by mutect2, pindel
- DNAH9 | c.13145dup p.K4383Efs*7 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- DNASE2 | c.46dup p.A16Gfs*24 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | called by mutect2, pindel
- DNPEP | c.1336dup p.Q446Pfs*28 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by pindel, varscan2
- DNPEP | c.993dup p.R332Afs*39 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel
- DOK6 | c.132dup p.F45Ifs*4 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- DOT1L | c.2227dup p.L743Pfs*11 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- DPEP1 | c.425dup p.G143Rfs*5 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- DPY19L2 | c.333dup p.I112Hfs*18 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- DRC7 | c.2258dup p.F754Ifs*22 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- DSCAML1 | c.1327dup p.A443Gfs*22 (on ENST00000321322; = p.A383Gfs*22 on NM_020693.4) | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- DST | c.7204dup p.Y2402Lfs*2 | Frame Shift Ins (INS) | VAF 7/80 reads (9%) | called by mutect2, pindel
- DTX3 | c.360dup p.G121Rfs*103 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- DUOX1 | c.2011dup p.V671Gfs*41 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- DUS2 | c.1337dup p.S447Ffs*11 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- DVL3 | c.2045dup p.P683Sfs*28 | Frame Shift Ins (INS) | VAF 6/67 reads (9%) | called by mutect2, pindel
- DYNC1LI2 | c.1261dup p.N421Kfs*2 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by pindel, varscan2
- DYRK1B | c.103dup p.L35Pfs*13 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel
- EBLN2 | c.280dup p.Q94Pfs*8 | Frame Shift Ins (INS) | VAF 12/119 reads (10%) | called by mutect2, pindel
- EFS | c.660dup p.S221Lfs*14 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- EHBP1L1 | c.4185dup p.A1396Cfs*85 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- EHMT1 | c.837dup p.V280Cfs*18 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- EHMT2 | c.1942dup p.R648Pfs*99 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- EIF3A | c.795dup p.P266Tfs*3 | Frame Shift Ins (INS) | VAF 9/99 reads (9%) | called by mutect2, pindel
- ENTPD4 | c.795dup p.T266Dfs*34 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- ENTPD8 | c.1238dup p.H414Afs*200 (on ENST00000371506 / NM_001033113.2; = p.H377Afs*200 on NM_198585.3) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- EPHB3 | c.553dup p.S185Ffs*60 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- EPN3 | c.280dup p.H94Pfs*44 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ERAP1 | c.719_727dup p.M242_S243insMKM | In Frame Ins (INS) | VAF 60/230 reads (26%) | called by mutect2, varscan2
- ERI3 | c.830dup p.A278Gfs*34 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | called by mutect2, pindel
- ERMAP | c.154dup p.L52Pfs*37 | Frame Shift Ins (INS) | VAF 3/35 reads (9%) | called by mutect2, pindel
- ESPNL | c.2933dup p.N978Kfs*3 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- ETHE1 | c.280dup p.L94Pfs*13 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- EVI5L | c.1189dup p.T397Nfs*130 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- EXD3 | c.1787dup p.P597Tfs*23 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- FAM102A | c.979dup p.D327Gfs*56 (on ENST00000373095 / NM_001035254.3; = p.D185Gfs*56 on NM_203305.2) | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- FAM135B | c.793dup p.D265Gfs*16 | Frame Shift Ins (INS) | VAF 7/66 reads (11%) | called by mutect2, pindel
- FAM161B | c.821dup p.C275Vfs*71 (on ENST00000651776; = p.C212Vfs*71 on NM_152445.3) | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- FAM167B | c.123dup p.S42Lfs*40 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel
- FAM53B | c.22dup p.S8Kfs*8 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- FAM83C | c.977dup p.V327Cfs*8 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- FAM83G | c.1754dup p.D585Efs*8 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- FANCF | c.534dup p.K179Efs*87 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by pindel, varscan2
- FARP2 | c.1362dup p.T455Hfs*48 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- FAT1 | c.9369dup p.E3124Rfs*13 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- FAT1 | c.1959dup p.A654Cfs*22 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by mutect2, pindel
- FAT2 | c.10920dup p.E3641Rfs*6 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel
- FBXL5 | c.84+1dup p.X28_splice | Splice Site (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- FBXO46 | c.676dup p.R226Pfs*10 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- FES | c.1346dup p.E450Gfs*8 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- FEZF2 | c.784dup p.H262Pfs*26 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, varscan2
- FGF23 | c.602dup p.A202Gfs*21 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- FGFBP3 | c.742dup p.L248Pfs*35 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by pindel, varscan2
- FHOD3 | c.1072dup p.D358Gfs*41 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by pindel, varscan2
- FKBP10 | c.505dup p.R169Pfs*29 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- FLRT1 | c.1721dup p.C574Wfs*26 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- FMN1 | c.2870dup p.G958Wfs*32 (on ENST00000616417 / NM_001277313.2; = p.G735Wfs*32 on NM_001103184.4) | Frame Shift Ins (INS) | VAF 10/108 reads (9%) | called by mutect2, pindel
- FMN1 | c.2678dup p.M894Nfs*39 (on ENST00000616417 / NM_001277313.2; = p.M671Nfs*39 on NM_001103184.4) | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, varscan2
- FNDC1 | c.3471dup p.K1158Efs*32 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by pindel, varscan2
- FOXO4 | c.601dup p.S201Kfs*10 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- FRMPD1 | c.3597dup p.L1200Tfs*10 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- FRMPD3 | c.2660dup p.G888Wfs*32 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by pindel, varscan2
- FRMPD3 | c.2901dup p.K968Qfs*33 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- FRMPD3 | c.4539dup p.E1514Rfs*7 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FRY | c.5955dup p.K1986Qfs*11 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- FTCD | c.1278dup p.K427Qfs*5 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FYCO1 | c.4054dup p.L1352Pfs*5 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- GAL3ST4 | c.659dup p.E221Rfs*48 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by pindel, varscan2
- GARRE1 | c.2625dup p.N876Qfs*7 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by pindel, varscan2
- GASK1B | c.472dup p.E158Gfs*3 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- GATAD2A | c.751dup p.A251Gfs*8 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by pindel, varscan2
- GBA2 | c.2398dup p.A800Gfs*12 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- GBF1 | c.4441dup p.D1481Gfs*52 (on ENST00000369983 / NM_001377137.1; = p.D1480Gfs*52 on NM_004193.3) | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- GEMIN4 | c.1969dup p.L657Pfs*9 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- GEMIN4 | c.927dup p.S310Qfs*2 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- GGCT | c.97dup p.L33Pfs*18 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- GIGYF1 | c.798dup p.R267Afs*16 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- GJA3 | c.378dup p.Q127Afs*199 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- GLA | c.615_629del p.L206_P210del | In Frame Del (DEL) | VAF 32/119 reads (27%) | called by mutect2, pindel, varscan2
- GLI3 | c.3872dup p.Q1292Pfs*12 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by mutect2, pindel
- GNB2 | c.731dup p.S245Lfs*2 | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | called by mutect2, pindel
- GOLGA2 | c.1988dup p.E664Gfs*34 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- GP6 | c.516_525del p.A173Efs*32 | Frame Shift Del (DEL) | VAF 26/55 reads (47%) | called by mutect2, pindel
- GPER1 | c.72dup p.N25Qfs*24 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, pindel
- GPR143 | c.488dup p.L164Pfs*22 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by pindel, varscan2
- GPR17 | c.977dup p.F327Lfs*4 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- GPR27 | c.1025dup p.N342Kfs*65 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- GPR55 | c.629dup p.R211Pfs*136 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, pindel
- GPR61 | c.757dup p.R253Pfs*120 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- GPR61 | c.881dup p.Q295Tfs*78 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel
- GPRASP1 | c.2646dup p.E883Rfs*20 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- GPRC5B | c.813dup p.A273Gfs*19 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel
- GPRIN2 | c.342dup p.A115Cfs*13 | Frame Shift Ins (INS) | VAF 6/37 reads (16%) | called by mutect2, pindel
- GPX7 | c.232dup p.H78Pfs*3 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- GRIK5 | c.2493dup p.R832Efs*4 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel
- GRIN1 | c.31dup p.L11Pfs*83 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- GRIN2B | c.4227dup p.T1410Hfs*49 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- GRIN2D | c.679dup p.A227Gfs*35 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- GRINA | c.164dup p.G56Rfs*71 | Frame Shift Ins (INS) | VAF 7/62 reads (11%) | called by pindel, varscan2
- GRINA | c.971dup p.A325Rfs*86 | Frame Shift Ins (INS) | VAF 8/101 reads (8%) | called by mutect2, pindel
- GSE1 | c.1577dup p.H526Qfs*34 | Frame Shift Ins (INS) | VAF 3/38 reads (8%) | called by mutect2, pindel
- GSG1L | c.674dup p.S226Lfs*22 (on ENST00000447459 / NM_001109763.2; = p.S71Lfs*22 on NM_144675.2) | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | called by mutect2, pindel
- GSN | c.1204dup p.T402Nfs*40 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- GSTZ1 | c.12dup p.K5Efs*44 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel
- H2BC15 | c.362dup p.Y122Vfs*10 (on ENST00000396980; = p.Y122Vfs*69 on NM_003520.4) | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- H3C12 | c.96dup p.T33Dfs*19 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- HARBI1 | c.233dup p.Y80Lfs*30 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, pindel, varscan2
- HCFC1 | c.4702dup p.A1568Gfs*148 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- HDAC6 | c.2405dup p.P803Tfs*20 | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | called by mutect2, pindel
- HECTD1 | c.6972dup p.S2325Ifs*6 | Frame Shift Ins (INS) | VAF 7/77 reads (9%) | called by pindel, varscan2
- HERC1 | c.13750dup p.I4584Nfs*53 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel
- HES1 | c.26dup p.N9Kfs*19 | Frame Shift Ins (INS) | VAF 7/68 reads (10%) | called by mutect2, pindel
- HFM1 | c.3411del p.K1137Nfs*44 | Frame Shift Del (DEL) | VAF 72/307 reads (23%) | called by pindel, varscan2
- HIC2 | c.1489dup p.A497Gfs*5 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- HIP1R | c.2279dup p.L761Pfs*35 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- HJV | c.255dup p.Y86Lfs*64 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- HK3 | c.385dup p.Q129Pfs*13 | Frame Shift Ins (INS) | VAF 6/67 reads (9%) | called by mutect2, pindel
- HNF4A | c.175dup p.L59Pfs*20 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- HOXB3 | c.571dup p.A191Gfs*20 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- HOXC10 | c.708dup p.A237Sfs*11 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- HSF1 | c.988dup p.L330Pfs*3 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- HTATSF1 | c.1087dup p.E363Gfs*15 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | called by mutect2, pindel, varscan2
- IBA57 | c.808dup p.H270Pfs*68 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | called by mutect2, pindel
- IFIT5 | c.1125dup p.H376Tfs*16 | Frame Shift Ins (INS) | VAF 11/111 reads (10%) | called by mutect2, pindel
- IGDCC3 | c.2338dup p.A780Gfs*16 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- IGDCC4 | c.2845+1dup p.X949_splice | Splice Site (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- IGHM | c.31dup p.L11Pfs*5 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- IGHV1-12 | n.47dup | Splice Region (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- IKZF1 | c.491dup p.K165Qfs*35 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- IL17C | c.558dup p.V187Rfs*74 | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | called by mutect2, pindel
- INHA | c.571dup p.H191Pfs*20 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- IPO4 | c.2989dup p.E997Gfs*18 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- IPO7 | c.2964_2972del p.R989_Q991del | In Frame Del (DEL) | VAF 41/296 reads (14%) | called by pindel, varscan2
- IRF4 | c.941dup p.V315Rfs*46 | Frame Shift Ins (INS) | VAF 9/91 reads (10%) | called by mutect2, pindel
- IRF5 | c.57dup p.W20Lfs*42 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- IRF7 | c.1025dup p.A343Sfs*72 (on ENST00000397566; = p.A330Sfs*72 on NM_001572.5) | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- ITPR3 | c.2586+1dup | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- JAG1 | c.1160dup p.T388Hfs*7 | Frame Shift Ins (INS) | VAF 8/86 reads (9%) | called by mutect2, pindel, varscan2
- KANK2 | c.1414dup p.T472Nfs*38 (on ENST00000586659 / NM_001379562.1; = p.T472Nfs*46 on NM_015493.7 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- KAT6B | c.1497dup p.I500Hfs*38 | Frame Shift Ins (INS) | VAF 10/100 reads (10%) | called by mutect2, varscan2
- KAT6B | c.5772dup p.M1925Hfs*121 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- KAZN | c.1466dup p.L490Pfs*21 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by pindel, varscan2
- KCNA3 | c.804dup p.T269Dfs*51 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- KCNF1 | c.458dup p.V154Rfs*202 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- KCNJ8 | c.19dup p.I7Nfs*42 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- KCNK16 | c.133dup p.D45Gfs*92 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel
- KCNK3 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- KCNK5 | c.1348dup p.Q450Pfs*5 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by pindel, varscan2
- KCNQ4 | c.1756dup p.I586Nfs*27 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- KCTD11 | c.582dup p.H195Sfs*85 (on ENST00000333751 / NM_001363642.1; = p.H156Sfs*85 on NM_001002914.2) | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- KIAA0586 | c.3392dup p.E1132Rfs*8 (on ENST00000619416 / NM_001244190.2; = p.E1071Rfs*8 on NM_014749.5) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.14825dup p.I4943Dfs*2 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- KIAA1614 | c.125dup p.Q43Tfs*4 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- KIAA1614 | c.1934dup p.R646Afs*19 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by pindel, varscan2
- KIF1C | c.1251dup p.T418Hfs*3 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- KIF24 | c.2160dup p.E721* | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- KIF26A | c.1225dup p.A409Gfs*54 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- KIFC3 | c.1761dup p.K588Efs*26 | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | called by mutect2, pindel
- KLF6 | c.141dup p.C48Lfs*11 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- KLHDC7A | c.237dup p.P80Afs*11 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- KLHL22 | c.871dup p.T291Nfs*83 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel
- KLHL22 | c.533dup p.N178Kfs*9 | Frame Shift Ins (INS) | VAF 8/88 reads (9%) | called by mutect2, pindel
- KLHL34 | c.1059dup p.T354Hfs*85 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel
- KMT5C | c.1319dup p.P441Tfs*20 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- KNCN | c.74dup p.S26Qfs*97 (on ENST00000481882 / NM_001322255.2; = p.S26Qfs*74 on NM_001097611.1) | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- KNL1 | c.3735dup p.G1246Rfs*19 (on ENST00000346991 / NM_170589.5; = p.G1220Rfs*19 on NM_144508.5) | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- KRT78 | c.171dup p.S58Vfs*4 | Frame Shift Ins (INS) | VAF 9/74 reads (12%) | called by mutect2, pindel
- LAMA5 | c.5749dup p.L1917Pfs*60 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, pindel
- LAMA5 | c.5431dup p.V1811Gfs*83 | Frame Shift Ins (INS) | VAF 5/64 reads (8%) | called by mutect2, pindel
- LAS1L | c.1455dup p.K486Qfs*36 | Frame Shift Ins (INS) | VAF 3/18 reads (17%) | called by mutect2, pindel
- LCE1D | c.185dup p.C63Lfs*28 | Frame Shift Ins (INS) | VAF 8/77 reads (10%) | called by pindel, varscan2
- LDB3 | c.548dup p.A185Sfs*12 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- LENG1 | c.748dup p.Q250Pfs*32 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, pindel
- LETM1 | c.195dup p.R66Qfs*52 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- LIG1 | c.1140dup p.L381Afs*64 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by pindel, varscan2
- LILRB2 | c.937dup p.L313Pfs*51 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- LIME1 | c.843dup p.S282Qfs*27 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- LINGO3 | c.1761dup p.N588Qfs*73 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- LLGL1 | c.698dup p.F234Lfs*15 | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | called by mutect2, pindel
- LMO7 | c.777dup p.E260* (on ENST00000357063; = p.E275* on NM_005358.5) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- LMTK2 | c.1243dup p.Q415Pfs*9 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- LPIN2 | c.2587dup p.L863Pfs*4 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by pindel, varscan2
- LRBA | c.26dup p.S10Ffs*7 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2
- LRIG1 | c.2159dup p.P721Sfs*17 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by pindel, varscan2
- LRP10 | c.1061dup p.G355Rfs*25 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- LRP5 | c.2473dup p.T825Nfs*45 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- LRRC30 | c.343dup p.L115Pfs*50 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- LRRC4 | c.76dup p.A26Gfs*29 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- LRRC7 | c.3805dup p.I1269Nfs*4 (on ENST00000651989 / NM_001370785.2; = p.I1236Nfs*4 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- LRRC8A | c.1251dup p.Q418Afs*23 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel
- LRRFIP1 | c.1518dup p.L507Tfs*20 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | called by mutect2, pindel
- LRRK1 | c.5390dup p.A1798Gfs*12 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel
- LRRN1 | c.2027dup p.L677Tfs*3 | Frame Shift Ins (INS) | VAF 7/73 reads (10%) | called by mutect2, pindel
- LRRN2 | c.1733dup p.T579Nfs*25 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- LRRN2 | c.1186dup p.L396Pfs*15 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- LRRN3 | c.1368dup p.I457Dfs*11 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- LRRTM1 | c.553dup p.R185Pfs*26 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- LSP1 | c.585dup p.T196Hfs*18 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- LTBP4 | c.2744dup p.A916Sfs*7 (on ENST00000308370 / NM_001042544.1; = p.A879Sfs*7 on NM_003573.2) | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- LTBR | c.1246dup p.E416Gfs*9 | Frame Shift Ins (INS) | VAF 3/35 reads (9%) | called by mutect2, pindel
- LTF | c.270dup p.Y91Lfs*72 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- LVRN | c.374dup p.L125Ffs*24 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- LY75 | c.125dup p.N42Kfs*19 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- LYPLAL1 | c.30dup p.R11Afs*11 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- MAGEC2 | c.322dup p.S108Ffs*7 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- MAMLD1 | c.802dup p.S268Kfs*2 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- MAN1A1 | c.536dup p.I180Nfs*30 | Frame Shift Ins (INS) | VAF 10/96 reads (10%) | called by pindel, varscan2
- MAN2B2 | c.1526dup p.V510Sfs*16 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- MANEA | c.980dup p.N327Kfs*14 | Frame Shift Ins (INS) | VAF 7/77 reads (9%) | called by mutect2, pindel
- MAP3K10 | c.598dup p.A200Gfs*14 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, varscan2
- MAP3K14 | c.541dup p.D181Gfs*2 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- MAP3K19 | c.3802dup p.A1268Gfs*44 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- MAPK8IP2 | c.1684dup p.D562Gfs*8 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by pindel, varscan2
- MAPKBP1 | c.3580dup p.Q1194Pfs*16 (on ENST00000456763 / NM_001128608.2; = p.Q1188Pfs*16 on NM_014994.3) | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- MATN2 | c.384dup p.H129Afs*55 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- MAVS | c.859dup p.A287Gfs*43 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- MB | c.457dup p.Q153Pfs*27 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- MCM2 | c.596dup p.K200Qfs*29 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- MCM3AP | c.4964dup p.E1656Rfs*65 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- MDGA1 | c.1910dup p.E638Gfs*81 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel
- MED12L | c.6139dup p.D2047Gfs*108 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | called by mutect2, pindel
- MED24 | c.1354dup p.L452Pfs*22 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- MEGF11 | c.329dup p.R111Pfs*45 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- MEGF8 | c.4664dup p.A1556Sfs*40 (on ENST00000251268 / NM_001271938.2; = p.A1489Sfs*40 on NM_001410.3) | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | called by mutect2, pindel
- MEPE | c.584dup p.K196Efs*26 | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | called by mutect2, pindel
- METTL22 | c.11dup p.A5Gfs*12 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- MEX3A | c.927dup p.D310Rfs*6 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- MFAP3L | c.56dup p.L19Ffs*11 | Frame Shift Ins (INS) | VAF 6/61 reads (10%) | called by mutect2, pindel
- MFN2 | c.488dup p.A164Gfs*24 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- MID1IP1 | c.242dup p.A82Rfs*89 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by pindel, varscan2
- MINAR1 | c.916dup p.M306Nfs*4 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- MKI67 | c.762dup p.E255Rfs*8 | Frame Shift Ins (INS) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- MLF2 | c.667dup p.R223Kfs*14 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- MLLT6 | c.1721dup p.L575Sfs*47 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | called by mutect2, pindel
- MLPH | c.235dup p.R79Kfs*27 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel
- MMD2 | c.226dup p.L76Pfs*80 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- MMRN2 | c.952dup p.Q318Pfs*48 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- MN1 | c.246dup p.L83Afs*72 | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | called by mutect2, varscan2
- MOGS | c.846dup p.S283* | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | called by mutect2, pindel
- MON1B | c.757dup p.L253Pfs*51 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- MUC17 | c.4277dup p.G1427Wfs*6 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | called by mutect2, pindel
- MUC2 | c.899dup p.L301Tfs*151 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- MUL1 | c.577dup p.A193Gfs*91 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- MYADM | c.530dup p.V178Gfs*? (on ENST00000336967; = p.V178Gfs*88 on NM_138373.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- MYBPC3 | c.2571dup p.S858Qfs*26 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by pindel, varscan2
- MYH13 | c.939dup p.F314Lfs*14 | Frame Shift Ins (INS) | VAF 5/53 reads (9%) | called by pindel, varscan2
- MYO7A | c.1992dup p.I665Hfs*46 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- MYO7A | c.5248dup p.E1750Gfs*15 | Frame Shift Ins (INS) | VAF 3/20 reads (15%) | called by mutect2, pindel
- MYOG | c.190dup p.Q64Pfs*8 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- NAPA | c.589dup p.L197Pfs*33 | Frame Shift Ins (INS) | VAF 11/108 reads (10%) | called by mutect2, pindel
- NAV2 | c.63dup p.A22Rfs*33 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- NBAS | c.6209dup p.A2071Sfs*10 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- NBEAL2 | c.5051dup p.L1685Tfs*15 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- NBEAL2 | c.6616dup p.L2206Pfs*19 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- NBR1 | c.2341dup p.E781Gfs*17 | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | called by pindel, varscan2
- NCKAP5L | c.2714dup p.G906Wfs*19 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- NDRG4 | c.496dup p.L166Pfs*49 (on ENST00000570248 / NM_001378344.1; = p.L198Pfs*49 on NM_020465.4 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- NECTIN1 | c.486dup p.Q163Afs*3 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | called by mutect2, pindel
- NEFL | c.1323dup p.Y442Lfs*18 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- NEFL | c.133dup p.A45Gfs*55 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- NEU2 | c.889dup p.H297Pfs*23 | Frame Shift Ins (INS) | VAF 5/51 reads (10%) | called by mutect2, pindel
- NFIA | c.1286dup p.N429Kfs*102 (on ENST00000403491 / NM_001134673.4; = p.N429Kfs*65 on NM_005595.5) | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel
- NFKB2 | c.2126dup p.T710Yfs*3 | Frame Shift Ins (INS) | VAF 8/77 reads (10%) | called by mutect2, varscan2
- NFX1 | c.2571dup p.T858Hfs*5 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- NHSL2 | c.611dup p.P205Tfs*11 (on ENST00000510661; = p.P571Tfs*11 on NM_001013627.2) | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by pindel, varscan2
- NIBAN2 | c.2026dup p.A676Gfs*10 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- NLRC5 | c.638dup p.N214Qfs*5 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- NLRP1 | c.2678dup p.S893Rfs*17 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- NLRP8 | c.1542dup p.A515Cfs*69 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | called by mutect2, pindel
- NOP53 | c.487dup p.R163Pfs*49 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel
- NOTCH3 | c.3213dup p.C1072Vfs*8 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- NOXRED1 | c.28dup p.L10Pfs*4 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- NPAP1 | c.317dup p.R107Efs*26 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- NPAS4 | c.2064dup p.W689Lfs*11 | Frame Shift Ins (INS) | VAF 5/58 reads (9%) | called by mutect2, pindel
- NPDC1 | c.411dup p.Q138Afs*75 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- NR1H3 | c.661dup p.Q221Pfs*5 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by pindel, varscan2
- NR2F1 | c.834dup p.A279Rfs*118 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- NR5A2 | c.1388dup p.N463Kfs*3 (on ENST00000367362 / NM_205860.3; = p.N417Kfs*3 on NM_003822.5) | Frame Shift Ins (INS) | VAF 14/123 reads (11%) | called by pindel, varscan2
- NRXN3 | c.1776dup p.S593Vfs*97 (on ENST00000557594 / NM_001272020.2; = p.S1017Vfs*97 on NM_004796.6) | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- NTRK3 | c.914dup p.R306Tfs*9 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by pindel, varscan2
- NUDT13 | c.365dup p.L122Ffs*5 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- NUDT17 | c.696dup p.G233Rfs*69 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by mutect2, pindel
- NUMA1 | c.3664dup p.R1222Kfs*4 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- NUMBL | c.889dup p.L297Pfs*33 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel
- NYAP1 | c.845dup p.L283Ifs*40 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- OBSCN | c.1401dup p.I468Hfs*100 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- OBSL1 | c.3630dup p.R1211Efs*54 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- OGDHL | c.2538dup p.S847Ifs*13 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel
- OR13A1 | c.723dup p.S242Qfs*93 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- OR2A12 | c.624dup p.P209Afs*84 | Frame Shift Ins (INS) | VAF 12/132 reads (9%) | called by mutect2, pindel
- OR4K1 | c.932dup p.N311Kfs*15 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- OR5F1 | c.438dup p.G147Rfs*24 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel
- OR6S1 | c.521dup p.A175Cfs*28 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | called by mutect2, pindel
- OR6S1 | c.91dup p.S31Ffs*24 | Frame Shift Ins (INS) | VAF 8/73 reads (11%) | called by pindel, varscan2
- OTUD5 | c.975dup p.R326Sfs*3 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by mutect2, pindel
- OTX1 | c.544dup p.I182Nfs*20 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- PABPC5 | c.234dup p.M79Hfs*4 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- PACS2 | c.840dup p.E281Rfs*11 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, pindel
- PALM2AKAP2 | c.1182dup p.G395Rfs*29 (on ENST00000259318 / NM_001136562.3; = p.G626Rfs*29 on NM_007203.5) | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- PANX2 | c.1738dup p.R580Pfs*184 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by mutect2, pindel
- PAPLN | c.2962dup p.Q988Pfs*11 (on ENST00000554301; = p.Q961Pfs*11 on NM_173462.4) | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by mutect2, pindel
- PARP10 | c.2158dup p.E720Gfs*48 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- PARP10 | c.59dup p.A21Cfs*12 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by pindel, varscan2
- PARP4 | c.855dup p.V286Sfs*5 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- PC | c.1655dup p.F553Lfs*61 | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | called by pindel, varscan2
- PCCA | c.348dup p.T117Hfs*3 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- PCDH10 | c.1261dup p.L421Pfs*27 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- PCDHB1 | c.748dup p.Q250Pfs*46 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- PCDHB7 | c.1468dup p.L490Pfs*238 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | called by mutect2, pindel
- PCDHGB2 | c.682dup p.I228Nfs*11 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- PCED1B | c.317dup p.L106Ffs*101 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- PCLO | c.8816dup p.C2940Vfs*3 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- PCNT | c.7122dup p.F2375Vfs*27 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- PCSK5 | c.4075dup p.R1359Pfs*15 | Frame Shift Ins (INS) | VAF 6/63 reads (10%) | called by mutect2, pindel
- PDCD11 | c.5428dup p.S1810Kfs*10 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- PDCD1LG2 | c.354dup p.V119Sfs*20 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by pindel, varscan2
- PDXK | c.931dup p.V311Gfs*37 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- PDZD2 | c.2099dup p.A701Sfs*8 | Frame Shift Ins (INS) | VAF 14/151 reads (9%) | called by mutect2, pindel
- PEX11G | c.723dup p.*242Lfs*48 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by mutect2, pindel
- PGAM2 | c.484dup p.R162Pfs*58 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel
- PHF23 | c.845dup p.R283* | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel
- PHF24 | c.305dup p.A103Cfs*11 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- PHIP | c.4223dup p.L1408Ffs*8 | Frame Shift Ins (INS) | VAF 8/109 reads (7%) | called by mutect2, pindel
- PHLDB1 | c.3766dup p.S1256Kfs*16 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- PIK3CD | c.2218dup p.L740Pfs*4 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- PIWIL2 | c.110dup p.A38Sfs*44 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- PKD1 | c.5481dup p.Q1828Afs*162 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- PLA2G4F | c.264dup p.C89Lfs*3 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- PLAAT5 | c.59dup p.P21Tfs*33 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- PLAT | c.1316dup p.D440Gfs*6 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- PLCB3 | c.1527dup p.X509_splice | Splice Site (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- PLEKHA6 | c.2527dup p.L843Pfs*28 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- PLEKHA7 | c.2807dup p.A937Gfs*51 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- PLEKHG3 | c.2167dup p.S723Ffs*10 (on ENST00000394691; = p.S779Ffs*10 on NM_001308147.2) | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PLEKHO2 | c.583dup p.Q195Pfs*20 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, varscan2
- PLXDC1 | c.128dup p.W44Lfs*37 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | called by mutect2, pindel
- PLXNA1 | c.3755dup p.G1253Rfs*23 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- PLXNA3 | c.1369dup p.V457Gfs*24 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.1381dup p.V461Gfs*139 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- PMPCA | c.523dup p.R175Pfs*5 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by mutect2, pindel
- POLE | c.3618dup p.P1207Afs*5 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- POLL | c.1019dup p.N340Kfs*43 | Frame Shift Ins (INS) | VAF 6/81 reads (7%) | called by mutect2, pindel
- POLR1G | c.658dup p.Q220Pfs*56 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- POLR3B | c.1119dup p.E374* | Frame Shift Ins (INS) | VAF 8/79 reads (10%) | called by pindel, varscan2
- POLR3E | c.1359dup p.L454Afs*180 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- POPDC2 | c.82dup p.A28Gfs*74 | Frame Shift Ins (INS) | VAF 10/116 reads (9%) | called by mutect2, pindel
- PPP1R26 | c.1700dup p.L567Ffs*18 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- PPP1R3A | c.276dup p.D93* | Frame Shift Ins (INS) | VAF 9/93 reads (10%) | called by pindel, varscan2
- PPP2R2D | c.1220dup p.K408* | Frame Shift Ins (INS) | VAF 7/75 reads (9%) | called by mutect2, pindel
- PRDM11 | c.1213dup p.V405Gfs*11 (on ENST00000530656 / NM_001359633.1; = p.V371Gfs*11 on NM_001256695.1) | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- PRDM15 | c.591dup p.T198Dfs*69 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- PRKCZ | c.1682dup p.D562Rfs*3 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- PROX1 | c.662dup p.Q222Pfs*41 | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- PRR12 | c.1517dup p.A507Cfs*26 (on ENST00000615927; = p.A1328Cfs*26 on NM_020719.3) | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, varscan2
- PRRG1 | c.506dup p.P170Afs*4 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, pindel
- PRRT2 | c.702dup p.H235Afs*8 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- PRSS55 | c.517dup p.V173Gfs*29 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- PRX | c.508dup p.L170Pfs*53 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- PSD4 | c.2499dup p.Q834Afs*5 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- PTCH1 | c.1932dup p.Y645Lfs*9 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by pindel, varscan2
- PTEN | c.820dup p.W274Lfs*24 | Frame Shift Ins (INS) | VAF 15/156 reads (10%) | called by mutect2, pindel
- PTGDR | c.725dup p.D242Efs*50 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- PTGFRN | c.1994dup p.S666Qfs*15 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | called by mutect2, pindel
- PTK7 | c.1502dup p.L502Afs*16 | Frame Shift Ins (INS) | VAF 5/55 reads (9%) | called by mutect2, pindel
- PTPN12 | c.1025+1_1025+2dup | Frame Shift Ins (INS) | VAF 9/63 reads (14%) | called by mutect2, varscan2
- PTPRF | c.5713dup p.Y1905Lfs*117 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- PTRH1 | c.20dup p.L7Ffs*9 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- RAB11FIP5 | c.1213dup p.E405Gfs*7 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- RADIL | c.1388dup p.A464Sfs*35 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, pindel
- RAI2 | c.167dup p.S57Ifs*129 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- RASAL1 | c.1695dup p.I566Hfs*42 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- RASGRP4 | c.1182dup p.Q395Afs*9 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- RBM10 | c.2072dup p.D691Efs*29 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- RBM26 | c.2003C>G p.S668C (on ENST00000438737 / NM_001366735.2; = p.S670C on NM_001286631.1) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- RDH12 | c.759dup p.F254Lfs*19 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- RECQL4 | c.3243dup p.F1082Lfs*13 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- RELL2 | c.500dup p.R168Qfs*8 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, pindel
- RELL2 | c.688dup p.Q230Pfs*24 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by pindel, varscan2
- REPIN1 | c.158dup p.G54Rfs*36 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- RERE | c.4390dup p.H1464Pfs*39 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- RERG | c.546dup p.T183Hfs*9 | Frame Shift Ins (INS) | VAF 11/112 reads (10%) | called by mutect2, pindel
- REV3L | c.8874dup p.G2959Rfs*46 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, pindel
- RGS11 | c.781dup p.H261Pfs*19 (on ENST00000397770 / NM_183337.3; = p.H240Pfs*19 on NM_003834.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- RHCE | c.934dup p.L312Pfs*6 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel
- RHOT2 | c.549dup p.A184Rfs*23 | Frame Shift Ins (INS) | VAF 6/76 reads (8%) | called by mutect2, pindel
- RHOV | c.502dup p.Q168Pfs*18 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel
- RIMS2 | c.3335dup p.T1114Nfs*4 (on ENST00000666250 / NM_001348490.2; = p.T922Nfs*4 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel
- RIN1 | c.1840dup p.E614Gfs*95 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- RINL | c.725dup p.E243Gfs*9 (on ENST00000591812 / NM_001195833.2; = p.E129Gfs*9 on NM_198445.4) | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- RIPK3 | c.131dup p.Y45Lfs*25 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- RIPPLY3 | c.449dup p.R153Qfs*16 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- RNASE10 | c.334dup p.L112Pfs*2 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- RNASE7 | c.344dup p.H116Afs*20 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- RNASEH2A | c.321dup p.R108Afs*12 | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- RNF151 | c.517dup p.E173Gfs*26 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel
- RNF31 | c.3128dup p.E1044Rfs*? | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- RNF40 | c.426dup p.T143Dfs*18 | Frame Shift Ins (INS) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- ROBO1 | c.4296dup p.H1433Sfs*7 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- ROM1 | c.381dup p.S128Efs*4 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- RP1L1 | c.5151dup p.T1718Hfs*4 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by pindel, varscan2
- RPS15 | c.167dup p.L57Afs*? | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- RPS6KA4 | c.224dup p.A76Rfs*62 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- RPS9 | c.256dup p.V86Gfs*4 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel
- RRAGC | c.152dup p.C52Lfs*7 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- RRP12 | c.3869dup p.N1290Kfs*22 | Frame Shift Ins (INS) | VAF 12/103 reads (12%) | called by mutect2, pindel, varscan2
- RRP12 | c.1602dup p.V535Sfs*11 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- RRP8 | c.1278dup p.F427Vfs*2 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- RTL9 | c.932dup p.L311Ffs*8 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | called by mutect2, pindel
- RTTN | c.3257G>T p.R1086M | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by mutect2, varscan2
- RUSC2 | c.3952dup p.R1318Pfs*9 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel
- RYR3 | c.4512dup p.N1505Qfs*46 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | called by mutect2, pindel
- S1PR2 | c.422dup p.S142Qfs*81 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel
- SALL3 | c.2443dup p.A815Gfs*59 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- SALL4 | c.1368dup p.Y457Lfs*7 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- SCAF1 | c.1111dup p.V371Gfs*282 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- SCAP | c.3426dup p.C1143Lfs*38 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- SCARB1 | c.1252dup p.E418Gfs*61 (on ENST00000415380 / NM_001367981.1; = p.E418Gfs*59 on NM_005505.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- SCD5 | c.834dup p.P279Sfs*3 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- SCIN | c.1879dup p.V627Gfs*3 (on ENST00000297029 / NM_001112706.3; = p.V380Gfs*3 on NM_033128.3) | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- SCML2 | c.1823dup p.P609Sfs*8 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- SCNN1G | c.176dup p.T60Hfs*57 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- SEMA4G | c.1915dup p.L639Pfs*9 (on ENST00000370250; = p.L644Pfs*9 on NM_017893.3) | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- SEPTIN12 | c.24dup p.S9Lfs*25 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- SERGEF | c.847dup p.T283Nfs*23 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- SERPINB6 | c.269dup p.F91Lfs*18 (on ENST00000612421 / NM_001271823.2; = p.F72Lfs*18 on NM_004568.6) | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | called by mutect2, pindel
- SERPINF2 | c.216dup p.D73Rfs*128 | Frame Shift Ins (INS) | VAF 3/38 reads (8%) | called by mutect2, pindel
- SETD1A | c.3781dup p.L1261Pfs*15 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- SETD6 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEZ6L2 | c.1278dup p.E427Rfs*7 (on ENST00000308713 / NM_001114099.3; = p.E357Rfs*7 on NM_012410.4) | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by mutect2, pindel
- SF3B2 | c.133+1dup | Frame Shift Ins (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- SHANK2 | c.3319dup p.L1107Pfs*4 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- SHCBP1 | c.1504dup p.L502Pfs*3 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by pindel, varscan2
- SHFL | c.556dup p.I186Nfs*61 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- SHROOM3 | c.1098dup p.S367Qfs*13 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel
- SHROOM3 | c.2234dup p.P746Afs*63 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel, varscan2
- SIAH1 | c.117dup p.E40* | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- SIK2 | c.2263dup p.R755Pfs*96 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- SIPA1L1 | c.298dup p.I100Nfs*8 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, pindel
- SIRT5 | c.641dup p.L216Afs*21 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | called by mutect2, pindel
- SLC12A7 | c.968dup p.C323Wfs*31 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- SLC17A7 | c.1629dup p.T544Hfs*40 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- SLC18A1 | c.464dup p.F156Ifs*66 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- SLC1A5 | c.1267dup p.A423Gfs*53 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- SLC22A11 | c.1426dup p.A476Gfs*47 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- SLC22A7 | c.218dup p.D74* | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- SLC22A8 | c.453dup p.I152Hfs*165 | Frame Shift Ins (INS) | VAF 7/50 reads (14%) | called by mutect2, varscan2
- SLC25A1 | c.537dup p.T180Dfs*66 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
241 further variants in this file (181 protein-altering or splice-affecting, 36 silent, 24 other) are not listed here.
